Surgical pathology report (de-identified scan), TCGA case TCGA-24-1560, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1560-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA
- PARAOVARIAN ADHESIONS WITH ASSOCIATED ADENOCARCINOMA

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING THE OVARIAN SURFACE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- PERITUBAL ADHESIONS

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- PROLIFERATIVE ENDOMETRIUM
- ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMAS
- ADENOMYOSIS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- SEROSAL ADHESIONS

PERITONEUM, LEFT PELVIC SIDEWALL, BIOPSY

- FIBROUS TISSUE WITH PSAMMOMA BODIES
- NO CARCINOMA IDENTIFIED

PERITONEUM, RIGHT PELVIC SIDEWALL, BIOPSY

- METASTATIC ADENOCARCINOMA

PERITONEUM, CUL-DE-SAC, BIOPSY

[page 2 of 6]
[REDACTED]
- METASTATIC ADENOCARCINOMA

DIAPHRAGM, BIOPSY

- SKELETAL MUSCLE & FIBROUS TISSUE WITH NO CARCINOMA IDENTIFIED

OMENTUM, OMENTECTOMY

- METASTATIC ADENOCARCINOMA, 0.6 CM IN GREATEST DIMENSION

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION

- METASTATIC ADENOCARCINOMA IN ONE OF FOUR LYMPH NODES (1/4)

LYMPH NODES, LEFT OBTURATOR, EXCISION

- NO CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)

LYMPH NODES, LEFT COMMON/PERI-AORTIC, EXCISION

- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION

- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

LYMPH NODES, RIGHT COMMON, EXCISION

- NO CARCINOMA IDENTIFIED IN FIVE LYMPH NODES (0/5)

LYMPH NODES, RIGHT OBTURATOR, EXCISION

- NO CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES (0/7)

LYMPH NODES, PARA-CAVAL, EXCISION

- NO CARCINOMA IDENTIFIED IN SIX LYMPH NODES (0/6)

[REDACTED]
By this signature, I attest that the above diagnosis is based upon my personal examination of the slides(and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation:

FS1A: Ovary, left, cystic excrescence, biopsy - "Invasive adenocarcinoma," by [REDACTED]

FS1B: Ovary, left, tumor, biopsy - "Invasive adenocarcinoma," by [REDACTED]

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up left adnexa," contains a partially serosa-covered tissue fragment (15.5 x 14 x 3.2 cm in greatest dimension) attached by a mostly smooth-surfaced cyst (13 cm in diameter). Requested by [REDACTED] to open the cyst in operating room. The cyst is filled with yellow clear fluid and has mostly smooth-lined internal wall three papillary excrescences (5.2 x 4.5 x 0.7 cm, 3.0 x 2.7 x 0.8 cm, and 1.7 x 1.5 x 0.6 cm in greatest dimension). One section of the partially serosa-covered tissue and one section of the excrescences taken for frozen section (FS1B and FS1A respectively). Tissue saved for [REDACTED]. The attached fallopian tube measures 5.5 cm in length and 0.5 cm in diameter, which grossly does not appear to be involved by tumor," by [REDACTED]

Microscopic Description and Comment:

Poorly differentiated papillary serous adenocarcinoma is present in the left ovary. Metastatic adenocarcinoma is present on the surface of the right ovary, in the right pelvic sidewall, cul-de-sac, and omentum. One of four left external iliac lymph nodes contains metastatic adenocarcinoma; the remaining 26 regional lymph nodes are free of carcinoma as are all other peritoneal biopsies. [REDACTED]

History:

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

The patient is a [REDACTED] with a left ovarian mass and increasing abdominal girth. Clinical diagnosis: Same. Operative procedure: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, pelvic lymph node dissection and multiple biopsies.

Specimen(s) Received:

A: LEFT ADNEXA
B: UTERUS, CERVIX RIGHT TUBE AND OVARY
C: LEFT PELVIC SIDE WALL
D: RIGHT PELVIC SIDE WALL
E: CUL DE SAC
F: LEFT EXTERNAL ILIAC
G: LEFT OBTURATOR LYMPH NODE
H: LEFT COMMON LYMPH NODE/ PERI AORTIC
I: RIGHT EXTERNAL ILIAC LYMPH NODE
J: RIGHT COMMON LYMPH NODE
K: RIGHT OBTURATOR LYMPH NODE
L: PARA CAVA LYMPH NODE
M: DIAPHRAGM BIOPSY
N: OMENTUM

Gross Description

Received are fourteen containers labeled with the patient's name and number. The first is further labeled "#1 left adnexa." It contains a tan-pink tissue fragment with papillary growth pattern. The tissue has maximum dimensions of 15.5 x 14 x 3.2 cm. One surface is lined by smooth serosa and a fragment of fallopian tube with a length of 4 cm and an external diameter of 1 cm is also identified. In addition a previously opened cyst is present. This contains three papillary excrescences on the internal surface with maximum dimensions of 5.2 x 4.5 x 0.7, 3.0 x 2.7 x 0.8 and 1.7 x 1.5 x 0.6 cm. Also within the container are two white cassettes labeled FS1A and FS1B. Labelled A - FS1A; A2-FS1B; A3 - A10 - sections of tumor; A11- section of fallopian tube. [REDACTED]

The second container is labeled "#2 uterus, cervix, right tube and ovary." It contains a hysterectomy specimen with attached right fallopian tube and ovary. The uterine corpus measures 6.0 cm superoinferiorly, 5.3 cm side to side and 7 cm anteroposteriorly. The cervix has a length of 3.0 cm in external diameter of 2.7 cm. The external os has a diameter of 0.2 cm. The uterus is bivalved in the coronal plane. The endocervix has a length of 3 cm and maximum diameter of 0.7 cm. The endometrial cavity has a length of 3.5 cm and maximum width of 3 cm. The endometrium is grossly unremarkable apart from a posterior endometrial polyp with a maximum dimension of 1.7 cm. Anterior and posterior intramural leiomyomas are identified. The anterior leiomyoma has a maximum dimension of 2.5 cm. The posterior leiomyoma has a maximum dimension of 1.7 cm. Both have white-pink, firm, whorled cut surface appearances. The right fallopian tube has a length of 7.5 cm and an external diameter of 0.8 cm. The right ovary has maximum dimensions of 1.9 x 1.5 x 0.7 cm. Attached to the surface of the ovary is a tan, firm nodule, grossly suggestive of tumor with maximum dimension of 1.5 cm. Labeled B1 - anterior endo-ectocervix; B2 - posterior endo-ectocervix; B3 - anterior endo-myometrium; B4 - posterior endo-myometrium; B5 - endometrial polyp; B6 - anterior leiomyoma; B7 - posterior intramural leiomyoma; B8 - right ovary including tumor; B9 - right fallopian tube. [REDACTED]

The third container is labeled "#3 left pelvic sidewall." It contains a single tan-brown tissue fragment with a maximum dimension of 0.5 cm labeled C1. [REDACTED]

The fourth container is labeled "#4 right pelvic sidewall." It contains a 2.5 x 2 x 0.5 cm fragment of soft tissue. One surface is pink-grey and glistening. The other surface is tan and papillary, grossly suggestive of tumor. [REDACTED]

The fifth container is labeled "cul-de-sac." It contains a fragment of tan-brown papillary tissue measuring 2.7 x 1 x 0.7 cm in maximum dimension. Innumerable friable tan tissue fragments are present within the container. These have an estimated volume of 2 cc. Sectioned from the larger tissue fragment labeled [REDACTED]

The sixth container is labeled "left external iliac lymph node." It contains a fragment of fibroadipose and lymphoid tissue with maximum dimensions of 5 x 3 x 0.5 cm. The tissue is dissected to show the presence of four lymph nodes ranging from 1.3 to 1.7 cm in maximum dimension. [REDACTED]

The seventh container is labeled "#7 left obturator lymph node." It contains a 4 x 2.5 x 1 cm fragment of fibroadipose

[page 4 of 6]
and lymph node tissue. The tissue is dissected to show the presence of two lymph nodes measuring 0.9 and 2.2 cm in maximum dimension.

The eighth container is labeled "#8 left common lymph node/periaortic." It contains a fragment of fibroadipose and lymph node tissue measuring 2 x 1 x 2 cm in maximum dimension.

The ninth container is labeled "#9 right external iliac lymph node." It contains fragment of fibroadipose and lymph node tissue measuring 3 x 2 x 0.5 cm.

The tenth container is labeled "#10 right common lymph node." It contains fragment of fibroadipose tissue measuring 3.5 x 2.5 x 0.7 cm in maximum dimension. It is dissected to show the presence of four nodes measuring between 1 and 1.5 cm in maximum dimension.

The eleventh container is labeled "#11 right obturator lymph node." It contains fragment of fibroadipose tissue measuring 3.5 x 2 x 0.7 cm in maximum dimension from which multiple lymph nodes are dissected.

The twelfth container is labeled "#12 para caval lymph node." It contains a 4.3 x 1.2 x 0.5 cm fragment of adipose and lymph node tissue from which multiple lymph nodes are dissected.

The thirteenth container is labeled "#13 diaphragm biopsy." It contains a tan tissue fragment measuring 0.5 cm x 0.1 x 0.1. Wrapped in tissue paper and stained with hematoxylin.

The fourteenth container is labeled "#14 omentum." It contains a cyst 20 x 4.5 x 1 cm fragment of omentum. No visible or palpable tumor deposits are identified on initial inspection. Tissue is serially sectioned at 0.5 cm intervals; firm tan tumor is palpable focally within the omentum.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is:
Left ovary only
4. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
5. Tumor IS identified on the ovarian surface(s).
6. Tumor DOES NOT invade the mesovarium.
7. Tumor DOES NOT invade the adjacent fallopian tube.
8. Tumor DOES invade the pelvic soft tissue.
9. Tumor involvement of the pelvic peritoneum is PRESENT.
10. Metastatic involvement of the EXTRAPELVIC peritoneum is ABSENT.
11. Metastatic involvement of the omentum is PRESENT.
12. The maximum dimension of tumor implants outside the true pelvis is 0.6 cm
13. Metastatic involvement of the uterine serosa is ABSENT.

[page 5 of 6]
14. Metastatic involvement of the endometrium is ABSENT.
15. Regional lymph node metastases are PRESENT.
16. The total number of regional lymph nodes examined is 30
17. The total number of metastatically-involved regional lymph nodes is 1
No extranodal extension is present.
18. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver

THE REGIONAL LYMPH NODES are classified as:

N1 one node contains metastatic tumor

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

19. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 94c84192-7da9-4409-8c33-87c687927d81 (TCGA-24-1560.464E1A20-B2D1-49C4-8DA5-11B8C0F96B4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).